Surgical pathology report (de-identified scan), TCGA case TCGA-N5-A4RA, project TCGA-UCS (Uterine Carcinosarcoma), tissue source site MSKCC, specimen TCGA-N5-A4RA-01A (Primary Tumor).

[page 1 of 3]
ICD O-3
Carcinosarcoma, Mixed
Mullerian Tumor 8950/3
Site CACF Uterus NOS C55.9
path Endometrium C54.1
JW 4/2/13

Specimens Submitted:

- 1: SP: Rt. external iliac lymph node
- 2: SP: Uterus, cervix, bilateral tubes and ovaries
- 3: SP: Right external iliac lymph node
- 4: SP: Right obturator lymph node
- 5: SP: Left obturator lymph node
- 6: SP: Omentum
- 7: SP: Right para-aortic lymph node
- 8: SP: Left para-aortic lymph node
- 9: SP: Left diaphragm bx
- 10: SP: Left paracolic gutter bx
- 11: SP: Right diaphragm bx
- 12: SP: Right paracolic gutter bx
- 13: SP: Right pelvis bx
- 14: SP: Left pelvis bx
- 15: SP: Left external iliac lymph node

DIAGNOSIS:

- 1) LYMPH NODE, RIGHT EXTERNAL ILIAC; EXCISION:
- MARKED FOLLICULAR HYPERPLASIA, IMMUNOSTAINS PENDING (SEE NOTE).
- NO CARCINOMA SEEN.
- 2) UTERUS, CERVIX, BILATERAL TUBES AND OVARIES; HYSTERECTOMY AND BILATERAL SALPINGO-OOPHORECTOMY:
- MALIGNANT MIXED MULLERIAN TUMOR OF ENDOMETRIUM (CARCINOSARCOMA), WITH HETEROLOGOUS ELEMENTS (RHABDOMYOSARCOMA).
- THE TUMOR INVADES TO > HALF OF MYOMETRIUM.
- THE MAXIMAL THICKNESS OF MYOMETRIAL INVASION IS 12 MM.
- THE THICKNESS OF THE MYOMETRIUM IN THE AREA OF MAXIMAL TUMOR INVASION IS 18 MM.
- NO ENDOCERVICAL INVASION IS IDENTIFIED.
- VASCULAR INVASION IS PRESENT.
- THE MYOMETRIUM SHOWS THE FOLLOWING ABNORMALITY: LEIOMYOMAS.
- ALL ADNEXAE ARE UNREMARKABLE.
- 3) LYMPH NODE, RIGHT EXTERNAL ILIAC; EXCISION:

** Continued on next page **

[page 2 of 3]
[REDACTED]

- ONE LYMPH NODE, NEGATIVE FOR CARCINOMA (0/1).

4) LYMPH NODES, RIGHT OBTURATOR; EXCISION:
- TWO LYMPH NODE, NEGATIVE FOR CARCINOMA (0/2).

5) LYMPH NODE, LEFT OBTURATOR; EXCISION:
- ONE LYMPH NODE, NEGATIVE FOR CARCINOMA (0/1).

6) OMENTUM; RESECTION:
- BENIGN FIBROADIPOSE TISSUE

7) LYMPH NODE, RIGHT PARA-AORTIC; EXCISION:
- GANGLION.
- METASTATIC CARCINOSARCOMA IN ONE LYMPH NODE (1/1)

8) LYMPH NODES, LEFT PARA-AORTIC; EXCISION:
- METASTATIC CARCINOSARCOMA INVOLVING TWO OF FOUR LYMPH NODES (2/4).

9) DIAPHRAGM, LEFT; BIOPSY:
- BENIGN FIBROUS TISSUE AND SKELETAL MUSCLE.

10) PARACOLIC GUTTER, LEFT; BIOPSY:
- BENIGN FIBROUS TISSUE AND SKELETAL MUSCLE.

11) DIAPHRAGM, RIGHT; BIOPSY:
- BENIGN FIBROUS TISSUE.

12) PARACOLIC GUTTER, RIGHT; BIOPSY:
- BENIGN FIBROADIPOSE TISSUE.

13) PELVIS, RIGHT; BIOPSY:
- BENIGN FIBROADIPOSE TISSUE.

14) PELVIS, LEFT; BIOPSY:
- BENIGN FIBROMUSCULAR TISSUE.

15) LYMPH NODES, LEFT EXTERNAL ILIAC; EXCISION:
- METASTATIC CARCINOSARCOMA INVOLVING ONE OF TWO LYMPH NODES (1/2).

NOTE: ALL LYMPH NODE METASTASES ARE COMPOSED PREDOMINANTLY OF CARCINOMA.
THE LYMPH NODES SHOW A MARKED AND DIFFUSE FOLLICULAR HYPERPLASIA.
IMMUNOSTAINS ARE BEING PERFORMED TO FURTHER CLASSIFY THESE FINDINGS. AN
ADDENDUM REPORT WILL FOLLOW.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF
THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED
THIS REPORT.

[REDACTED]

*** Report Electronically Signed Out *** [REDACTED]

[REDACTED]

[page 3 of 3]
Procedures/Addenda:
Addendum

Addendum Diagnosis

ADDENDUM

TISSUE SITE: RIGHT EXTERNAL ILIAC LYMPH NODE:

- LYMPH NODE WITH MARKED REACTIVE FOLLICULAR AND INTERFOLLICULAR HYPERPLASIA.
- IMMUNOHISTOCHEMICAL STUDIES (CD3, CD5, CD10, CD20, BCL-2, BCL-6, CYCLIN D1, AND MIB-1) SHOW A PATTERN CONSISTENT WITH REACTIVE CHANGES.

Source: NCI Genomic Data Commons file a5940d8a-eaf2-46b7-9dd2-e3f62c047eee (TCGA-N5-A4RA.24ADBD38-726C-4778-B41A-C0517A6905DF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).